Somatic mutation profile of tumor specimen TCGA-CK-6751-01A (aliquot TCGA-CK-6751-01A-11D-1835-10) from TCGA case TCGA-CK-6751, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CK-6751-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19813f61-99e2-481c-9ccb-da69c17ffd6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-6751-10A (Blood Derived Normal), aliquot TCGA-CK-6751-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4de519a4-935c-41cd-95bd-186809e224f0

The open-access MAF lists 187 somatic variants for this specimen: 144 protein-altering or splice-affecting, 40 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 40, Nonsense Mutation 12, Splice Region 4, Frame Shift Del 4, Frame Shift Ins 3, Intron 1, RNA 1, Splice Site 1, In Frame Del 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GJA3 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs864309687, CM071794, COSV53834152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/103 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYH2 | c.4537C>T p.Q1513* | Nonsense Mutation (SNP) | VAF 43/164 reads (26%) | catalogued as rs929311433, COSV55435848; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOX9 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 30/45 reads (67%) | catalogued as rs1057518216, CM1512588, COSV55430247; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4637G>A p.R1546H (on ENST00000272895 / NM_173076.3; = p.R1228H on NM_015657.3) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274612827, COSV55956227, COSV55978034; called by muse, mutect2, varscan2
- ACSL4 | c.851G>T p.R284L (on ENST00000340800 / NM_022977.2; = p.R243L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as COSV100538223; called by muse, mutect2, varscan2
- ACTBL2 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV101379203; called by muse, mutect2, varscan2
- ACVR1B | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231186; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2443G>A p.G815S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433260668, COSV54999079, COSV55004765; called by muse, mutect2, varscan2
- ADGRL3 | c.2231G>A p.S744N (on ENST00000506720 / NM_001322402.2; = p.S676N on NM_015236.6) | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.566); catalogued as COSV72230564; called by muse, mutect2, varscan2
- ADGRV1 | c.1742A>T p.N581I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV101315295; called by muse, mutect2, varscan2
- AHNAK | c.6175C>T p.P2059S | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as rs537151833, COSV99945153; called by muse, mutect2, varscan2
- ANKRD30A | c.1295del p.A432Efs*3 (on ENST00000611781; = p.A376Efs*3 on NM_052997.2) | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | catalogued as COSV64624024; called by mutect2, pindel, varscan2
- AP3B2 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs766260323, COSV55616886; called by muse, mutect2, varscan2
- APC | c.4725del p.E1576Kfs*74 | Frame Shift Del (DEL) | VAF 25/52 reads (48%) | catalogued as COSV57391127; called by mutect2, pindel, varscan2
- ARHGAP20 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52818950; called by muse, mutect2, varscan2
- ARHGEF15 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.384); catalogued as rs766415435, COSV62724296; called by muse, mutect2, varscan2
- ASB2 | c.1670G>T p.R557L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); catalogued as COSV100279170; called by muse, mutect2, varscan2
- ATAD3B | c.610C>T p.R204* (on ENST00000308647; = p.R310* on NM_031921.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 62/168 reads (37%) | catalogued as rs751720138, COSV58020875; called by muse, mutect2, varscan2
- BICRA | c.2465G>A p.C822Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV101194208; called by muse, mutect2, varscan2
- BMX | c.646T>C p.Y216H | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100564244; called by muse, mutect2, varscan2
- BPIFC | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100300653; called by muse, mutect2, varscan2
- CACNA1A | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.943); catalogued as COSV64197983; called by muse, mutect2, varscan2
- CACNA1B | c.3844G>A p.V1282I | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.822); catalogued as COSV99494446; called by muse, mutect2, varscan2
- CACNA1E | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.379); catalogued as COSV100701141; called by muse, mutect2, varscan2
- CCDC160 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100892082; called by muse, mutect2, varscan2
- CCDC198 | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99371077; called by muse, mutect2, varscan2
- CDH4 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs751431226, COSV64652166; called by muse, mutect2, varscan2
- CENPF | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100871405; called by muse, mutect2, varscan2
- CHD5 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1215979211, COSV52420223; called by muse, mutect2, varscan2
- CHRNA4 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.302); catalogued as rs76895198, COSV64718380; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CHURC1 | c.316G>A p.D106N (on ENST00000549115 / NM_001204063.1; = p.D107N on NM_145165.3) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as COSV100767388; called by muse, mutect2, varscan2
- CILP2 | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs1046163953, COSV52275234; called by muse, mutect2, varscan2
- COL20A1 | c.3359G>A p.G1120D | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58917218; called by muse, mutect2, varscan2
- DAB2 | c.1484T>G p.V495G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100297717; called by muse, mutect2, varscan2
- DCST1 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV55059409; called by muse, mutect2, varscan2
- DGKD | c.242C>T p.T81M (on ENST00000264057 / NM_152879.3; = p.T37M on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs547448630, COSV51078287; called by muse, mutect2, varscan2
- DLGAP2 | c.1899C>A p.S633R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101420964; called by muse, mutect2, varscan2
- EGFL6 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs573773218, COSV63634515; called by muse, mutect2, varscan2
- ETFB | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV58536015; called by muse, mutect2, varscan2
- EXOSC8 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99523923; called by muse, mutect2, varscan2
- FKBP14 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.992); catalogued as COSV99767012; called by muse, mutect2, varscan2
- FRMPD3 | c.5339C>A p.A1780D | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99345400; called by muse, mutect2, varscan2
- FSCN1 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751111507, COSV100434983; called by muse, mutect2, varscan2
- FXYD5 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV61568637; called by muse, mutect2, varscan2
- GAD2 | c.78G>A p.A26= | Splice Region (SNP) | VAF 29/78 reads (37%) | catalogued as COSV52153247, COSV52172517; called by muse, mutect2, varscan2
- GALNT13 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs865891391, COSV67214066; called by muse, mutect2, varscan2
- GALNT17 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775779137, COSV61150179, COSV61154998; called by muse, mutect2, varscan2
- GLUD2 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV100046551; called by muse, mutect2, varscan2
- GRM1 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51131498; called by muse, mutect2, varscan2
- GRSF1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV99635423; called by muse, mutect2, varscan2
- GSPT2 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.557); catalogued as rs782167047, COSV61214341; called by muse, mutect2, varscan2
- HDX | c.96G>C p.Q32H | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99946364; called by muse, mutect2, varscan2
- HEATR6 | c.2990C>T p.T997I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs750800169, COSV51745730; called by muse, mutect2, varscan2
- HJURP | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100982533, COSV100982582; called by muse, mutect2, varscan2
- HLA-B | c.343+1G>A p.X115_splice | Splice Site (SNP) | VAF 22/75 reads (29%) | catalogued as rs1168937188, COSV69520345, COSV69521733; called by muse, mutect2, varscan2
- IER5 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100849649; called by muse, mutect2, varscan2
- IFNLR1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs146955345; called by muse, mutect2, varscan2
- IGFALS | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1448256452, COSV51906144, COSV99236291; called by muse, mutect2, varscan2
- IGHG3 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs776442350; called by muse, mutect2, varscan2
- ITFG2 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV99957935; called by muse, mutect2, varscan2
- ITGB2 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs574757270, COSV100185485; called by muse, mutect2, varscan2
- KCNK3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.036); catalogued as rs773773071, COSV100256562; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNN1 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99715523; called by muse, mutect2, varscan2
- KIR3DL2 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1176749891; called by muse, mutect2
- KLHL1 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1036898745, COSV100916841, COSV100916947; called by muse, mutect2, varscan2
- KLHL34 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.025); catalogued as rs1464771579, COSV65279204, COSV65280308; called by muse, mutect2, varscan2
- KSR2 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60386582; called by muse, mutect2, varscan2
- LARP1 | c.1001G>A p.R334Q (on ENST00000518297 / NM_033551.3; = p.R257Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.248); catalogued as rs779604829, COSV100303303, COSV60426153; called by muse, mutect2, varscan2
- LRRN3 | c.1270G>C p.A424P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100066008; called by muse, mutect2, varscan2
- LTBP2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99999447; called by muse, mutect2, varscan2
- MDM1 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100291512; called by muse, mutect2
- MINAR1 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.244); catalogued as rs763508779, COSV59583382; called by muse, mutect2, varscan2
- MTHFSD | c.278C>T p.T93M (on ENST00000360900 / NM_001159377.2; = p.T92M on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs779426310, COSV59803241; called by muse, mutect2, varscan2
- MYF5 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1269683532, COSV57354981, COSV57355677; called by muse, mutect2, varscan2
- MYOCD | c.2379G>T p.Q793H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV58503665; called by muse, mutect2, varscan2
- NAV2 | c.5496C>T p.V1832= (on ENST00000396087 / NM_001244963.2; = p.V1776= on NM_182964.6) | Splice Region (SNP) | VAF 59/189 reads (31%) | catalogued as rs1308525401, COSV100215863; called by muse, mutect2, varscan2
- NDST1 | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs141752622; called by muse, mutect2, varscan2
- NEUROG1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747790479, COSV59082077; called by muse, mutect2, varscan2
- NLRP2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs557849528, COSV99671718; called by muse, mutect2
- NLRP7 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.511); catalogued as COSV60174420; called by muse, mutect2, varscan2
- NONO | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV52137681; called by muse, mutect2, varscan2
- OR10J3 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs759745047, COSV59955653; called by muse, mutect2
- OR8H3 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100538678, COSV57908287, COSV57908569; called by muse, varscan2
- PADI4 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as rs780966400, COSV64922941; called by mutect2, varscan2
- PAWR | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs1315510293, COSV100174015; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHB8 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 53/406 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); catalogued as COSV99175180; called by muse, mutect2, varscan2
- PCDHGA6 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.036); catalogued as rs1202404480, COSV53908286; called by muse, mutect2, varscan2
- PCM1 | c.5758G>T p.E1920* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100278730; called by muse, mutect2
- PIGO | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.269); catalogued as rs537260013, COSV53055365; ClinVar: uncertain significance; called by mutect2, varscan2
- POLD1 | c.3119A>G p.E1040G | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV54530602; called by muse, mutect2, varscan2
- POLR3A | c.2888A>G p.D963G | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs761205136, COSV100965505; called by muse, mutect2, varscan2
- PRAME | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs116965324, COSV67161168; called by muse, mutect2, varscan2
- PRPS1L1 | c.835_837del p.E279del | In Frame Del (DEL) | VAF 42/117 reads (36%) | catalogued as COSV72649892; called by mutect2, pindel, varscan2
- PSG4 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54935691; called by muse, mutect2
- RAB39B | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV65624487; called by muse, mutect2, varscan2
- RAD21 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV52056786, COSV99814634, COSV99815340; called by muse, mutect2, varscan2
- ROBO2 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV59911254; called by muse, mutect2, varscan2
- RTCB | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs751776473, COSV53278757; called by muse, mutect2, varscan2
- SAG | c.479G>A p.S160N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101300629; called by muse, mutect2, varscan2
- SERPINA3 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.027); catalogued as COSV101261592; called by muse, mutect2, varscan2
- SH3BP5 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.485); catalogued as rs566960315, COSV53743424; called by muse, mutect2, varscan2
- SIGLEC7 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV58315090, COSV99978335; called by muse, mutect2, varscan2
- SLFN5 | c.1204G>T p.G402* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as rs1204479641, COSV55483602; called by muse, mutect2, varscan2
- SLITRK4 | c.2473C>G p.L825V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100567076, COSV62025409; called by muse, mutect2, varscan2
- SLITRK4 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567077; called by muse, mutect2, varscan2
- SPACA3 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs200269504, COSV52191162; called by muse, mutect2, varscan2
- SPATA6 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.053); catalogued as rs201878636, COSV100892992; called by muse, mutect2, varscan2
- SPOCK3 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as rs779142326, COSV100691405; called by muse, mutect2, varscan2
- SPTA1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs764157190, COSV63751440; called by muse, mutect2, varscan2
- STAB1 | c.5993G>A p.R1998H | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770945357, COSV58742667; called by muse, mutect2, varscan2
- SYT5 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV99670567; called by muse, mutect2
- TAP1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs572060702, COSV100841064; called by muse, mutect2, varscan2
- TBC1D2 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100579612; called by muse, mutect2, varscan2
- TECTB | c.906G>A p.R302= | Splice Region (SNP) | VAF 16/64 reads (25%) | catalogued as rs776953089, COSV65595218; called by muse, mutect2, varscan2
- TEX30 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV65696940; called by muse, mutect2, varscan2
- TGFBR1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.483); catalogued as rs1554698880, COSV66625965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGFBR1 | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV100895237; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1739T>G p.I580S | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99304594; called by muse, mutect2, varscan2
- TMCO1 | c.303G>A p.L101= (on ENST00000612311 / NM_001256164.1; = p.L50= on NM_019026.6) | Splice Region (SNP) | VAF 62/166 reads (37%) | catalogued as rs764501911, COSV100903088; called by mutect2, varscan2
- TMEM115 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99223390; called by muse, mutect2, varscan2
- TMEM169 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.855); catalogued as rs777361974, COSV55265208; called by muse, mutect2, varscan2
- TMEM35A | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | catalogued as COSV54507248; called by muse, mutect2, varscan2
- TNXB | c.7123C>A p.Q2375K (on ENST00000647633; = p.Q2128K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64487971; called by muse, mutect2, varscan2
- TRAPPC9 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.635); catalogued as rs141596857; called by muse, mutect2, varscan2
- TRIO | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 37/84 reads (44%) | catalogued as COSV60078509, COSV60094751; called by muse, mutect2, varscan2
- TSSK2 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99350531; called by mutect2, varscan2
- TUT7 | c.113A>C p.D38A | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs2378696, COSV99462239; called by muse, mutect2, varscan2
- UBA5 | c.605G>A p.W202* | Nonsense Mutation (SNP) | VAF 36/100 reads (36%) | catalogued as COSV99393037; called by muse, mutect2, varscan2
- USH2A | c.12559C>T p.R4187C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs760177550, COSV56351624; called by muse, mutect2, varscan2
- WASF3 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs145251421, COSV58964820; called by muse, mutect2, varscan2
- WNT8A | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs897535340, COSV100842993; called by muse, mutect2, varscan2
- YY1AP1 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs760613801, COSV55122457, COSV99803227; called by muse, mutect2, varscan2
- ZBTB38 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs200031071; called by muse, mutect2, varscan2
- ZFPM1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765381904, COSV100128121; called by muse, mutect2, varscan2
- ZNF257 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV101447968, COSV99078261; called by muse, mutect2, varscan2
- ACVR1B | c.1406_1415dup p.M472Ifs*112 | Frame Shift Ins (INS) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- ACVR2A | c.1310dup p.R438Efs*19 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | called by mutect2, varscan2
- CD300LD | c.466dup p.L156Pfs*48 | Frame Shift Ins (INS) | VAF 30/89 reads (34%) | called by mutect2, pindel, varscan2
- MST1R | c.2274_2280del p.S761Pfs*11 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by mutect2, varscan2
- PANX1 | c.674_690del p.L225Pfs*50 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- PRAMEF5 | c.390G>T p.R130S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, varscan2
- ARHGAP15 | c.885G>A p.P295= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as rs752498477, COSV54501264; called by muse, mutect2, varscan2
- BASP1 | c.561C>T p.P187= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100493438, COSV100493561; called by muse, mutect2, varscan2
- COL4A5 | c.3762T>G p.P1254= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100086106; called by muse, mutect2
- DCAF8 | c.465C>T p.L155= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV58783804, COSV58786012; called by muse, mutect2, varscan2
- DENND4A | c.384C>T p.P128= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs763186284, COSV101475235; called by muse, mutect2, varscan2
- DNAJC5B | c.63C>T p.Y21= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs764193345, COSV52535529; called by muse, mutect2, varscan2
- ESPL1 | c.1734G>A p.P578= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs144474323; called by muse, mutect2, varscan2
- FREM2 | c.1788G>T p.L596= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99746065; called by muse, mutect2, varscan2
- GCC2 | c.1857G>A p.R619= | Silent (SNP) | VAF 69/183 reads (38%) | catalogued as COSV100565154; called by muse, mutect2, varscan2
- HGS | c.2199G>A p.A733= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as rs140803494; called by muse, mutect2, varscan2
- ITGA4 | c.645C>T p.A215= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as COSV99275559; called by muse, mutect2, varscan2
- KCNB1 | c.873T>C p.N291= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1292638459, COSV100870358, COSV100870578; called by muse, mutect2, varscan2
- KRT31 | c.144C>T p.C48= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs764087202, COSV52435145; called by muse, mutect2, varscan2
- LRCH4 | c.1182G>A p.R394= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100052663; called by muse, mutect2
- LRP8 | c.300C>T p.H100= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs779936452, COSV100035895; called by muse, mutect2, varscan2
- LRRN3 | c.1419C>T p.F473= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs11979902, COSV100066009, COSV57818433; called by muse, mutect2, varscan2
- MAGEC1 | c.36G>A p.P12= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV99594601; called by muse, mutect2, varscan2
- MED25 | c.618G>A p.P206= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs772693264, COSV100456974; called by muse, mutect2, varscan2
- MFF | c.606G>A p.S202= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs555978161, COSV58825984; called by muse, mutect2, varscan2
- MTX2 | c.282C>T p.A94= | Silent (SNP) | VAF 49/170 reads (29%) | catalogued as COSV50888060; called by muse, mutect2, varscan2
- NLGN4X | c.2040C>T p.A680= | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as rs763243806, COSV99319407; called by muse, mutect2, varscan2
- NLRP3 | c.3078G>A p.L1026= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100275047, COSV100276616; called by muse, mutect2, varscan2
- NOTCH2 | c.1923T>C p.N641= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs142022032; called by muse, mutect2, varscan2
- OR56A1 | c.96G>T p.L32= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV100360352; called by muse, mutect2, varscan2
- PDGFRA | c.2988G>A p.E996= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99955191; called by muse, mutect2, varscan2
- PHC1 | c.2469C>T p.C823= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs142710389; called by muse, mutect2, varscan2
- PLCB1 | c.498A>G p.E166= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV62050531; called by mutect2, varscan2
- PLCH2 | c.933C>T p.S311= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1294910876, COSV53942872; called by muse, mutect2, varscan2
- POU3F4 | c.60G>A p.A20= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV64539799; called by muse, mutect2, varscan2
- PSMD4 | c.459G>T p.L153= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as COSV64393135; called by muse, mutect2, varscan2
- RIMBP2 | c.858C>T p.D286= | Silent (SNP) | VAF 31/182 reads (17%) | catalogued as rs1187857600, COSV55487950; called by muse, mutect2, varscan2
- RNF180 | c.651C>A p.G217= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99684263; called by muse, mutect2, varscan2
- RUBCN | c.2472G>A p.K824= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV99582875; called by muse, mutect2, varscan2
- SCN5A | c.3501C>T p.C1167= (on ENST00000333535 / NM_198056.3; = p.C1166= on NM_000335.5) | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100345815; called by muse, mutect2, varscan2
- SERPING1 | c.165C>T p.F55= | Silent (SNP) | VAF 54/125 reads (43%) | catalogued as COSV53542023; called by muse, mutect2, varscan2
- SOHLH2 | c.576G>A p.S192= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as rs376868741; called by muse, mutect2, varscan2
- SSPN | c.198C>T p.A66= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs747147935, COSV54381067; called by muse, mutect2, varscan2
- TUBGCP2 | c.339G>A p.V113= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs756559059, COSV99427060; called by muse, mutect2, varscan2
- USP45 | c.996A>G p.E332= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100569409; called by muse, mutect2, varscan2
- WNK3 | c.4599G>A p.L1533= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as COSV100670601, COSV63614111; called by muse, mutect2, varscan2
- DCHS2 | n.2793G>A | RNA (SNP) | VAF 20/58 reads (34%) | catalogued as rs141492205, COSV59732692; called by muse, mutect2, varscan2
- MFRP | chr11:119346127 G>A | 5'Flank (SNP) | VAF 8/21 reads (38%) | catalogued as rs147490836; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TOR1AIP2 | c.-146-12112C>A | Intron (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100857250; called by muse, mutect2, varscan2
